Surgical pathology report (de-identified scan), TCGA case TCGA-29-1785, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site Duke, specimen TCGA-29-1785-01A (Primary Tumor).

[page 1 of 4]
TCGA-29-1785

Surg Path**CLINICAL HISTORY:**

Abdominal/pelvic swelling.

GROSS EXAMINATION:

A. "Omental nodule (Afl)", received fresh for frozen section is a 3.2 x 3 x 1 cm aggregate of tan-white nodular soft tissue fragments, a representative of section of which is frozen as Afl; frozen section remnant in block A1. An additional representative section is submitted in block A2.

B. "Omentum", received fresh and placed in formalin is a 37 x 33.5 x 3.8 cm aggregate of fibromembranous fatty tissue remarkable for numerous nodules ranging from 0.4 cm diameter up to a confluence of nodules 14 cm in greatest dimension. Serial sectioning of the nodules reveals a soft, circumscribed, white-tan cut surface, with larger nodules demonstrating focal hemorrhage and softening. Representative sections of smaller nodules are submitted in block B1 and representative of larger nodules in block B2.

C. "Right tube and ovary", received fresh and placed in formalin is a 208 gram, 9 x 7.5 x 7.3 cm ovary with a 9 cm long, 0.3 cm diameter fallopian tube adherent to and expanded over the surface. The surface of the ovary is primarily smooth with focal granular and papillary excrescences comprising approximately 10% of the surface. There is also a 2 x 2 cm fibrofatty adhesion. The ovary is serially sectioned to demonstrate a soft tan-yellow primary solid cut surface with focal cystic areas (serous and serosanguineous cysts) the largest of which is 2.1 cm in diameter. Representative sections are submitted as follows:

BLOCK SUMMARY:

C1- surface excrescences.

C2-C4- representative of cut surface cystic and solid components.

C5- fallopian tube.

D. "Left gutter", received fresh and placed in formalin is a 2.4 x 2.1 x 0.9 cm aggregate of pink-tan fatty tissue entirely submitted in block D1.

E. "Left tube and ovary", received fresh and placed in formalin is an 87 gram specimen consisting of a 2.5 x 1.5 x 1.2 cm ovary with a corrugated, white-tan surface and on cut section is soft, homogenous, and white-tan. The fallopian tube, 3.2 cm long x 0.6 cm in diameter, is fimbriated, purple-tan, and grossly unremarkable. Representative sections of the left adnexa are submitted in blocks E1-E2.

F. "Cul de sac nodule", received fresh and placed in formalin is a 2.4 x 1.1 x 1 cm tan-white nodular soft tissue fragment which is serially sectioned, with representative section in block F1.

G. "Rectal/sigmoid", received fresh and placed in formalin are two lengths of bowel (18 cm long x 3 cm diameter, and 6.5 cm long x 2.5 cm diameter) with attached mesenteric fat. The larger segment of bowel demonstrates a diffusely adhered serosa covered by innumerable tumor nodules from 0.5 cm in diameter up to confluent nodules 6.5 cm in greatest dimension. The larger bowel segment is opened to demonstrate a lumen focally distorted and narrowed by tumor compression and focal dusky mucosa. Serial sectioning demonstrates that the tumor does not arise in the mucosa.

The smaller fragment also demonstrates diffuse serosal adhesions and tumor nodules. Serial sectioning demonstrates that the tumor does not narrow or

[page 2 of 4]
compress the lumen or appear to arise from the mucosa, which is diffusely dusky but otherwise unremarkable.

Representative sections of the specimen are submitted as follows:

BLOCK SUMMARY:

- G1- mucosal margins, larger specimen.
- G2-G3- mucosa with respect to adjacent tumor., larger specimen.
- G4- representative serosal and mesenteric fat nodules, larger specimen.
- G5- mucosal margin, smaller specimen.
- G6-G7- representative serosal and mesenteric fat nodules, smaller specimen.

H. "Right pelvic lymph node", received fresh and placed in formalin is a 3.9 x 3.3 x 1 cm aggregate of pink-yellow soft fatty tissue serially sectioned to demonstrate a 2.3 x 2.2 x 1 cm soft tan-brown hemorrhagic nodule and three lymph node candidates 0.4 cm in diameter each. A representative section of the nodule is submitted in block H1 and the remaining three small lymph node candidates are submitted in block H2.

I. "Bladder flap mass", received fresh and placed in formalin is a 5.4 x 4.5 x 3.9 cm aggregate of brown hemorrhagic tissue serially sectioned to demonstrate a soft white to necrotic cut surface with focal hemorrhage, a representative of which is submitted in block I1.

J. "Left pelvic lymph node", received fresh and placed in formalin is a 1.1 x 1 x 0.8 cm lymph node candidate which is bisected and entirely submitted in block J1.

K. "Donut", received fresh and placed in formalin is a 6 cm long metal device containing an annular fragment of mucosa and staple line, a representative section of which is submitted in block K1.

L. "Spleen", received fresh and placed in formalin is a 212 gram, 13.6 x 8 x 4.4 cm red-brown spleen remarkable for 2.2 x 1.8 cm subcapsular hematoma and two areas of torn/ disrupted capsule, the largest of which is 6.4 x 2.5 cm. Serial sectioning demonstrates a grossly unremarkable parenchyma with no masses identified. Representative sections are submitted as follows:

BLOCK SUMMARY:

- L1- subcapsular hematoma.
- L2- capsule defect.
- L3- normal peripheral and central spleen.

INTRA OPERATIVE CONSULTATION:

A. "Omental nodule": AF1- poorly differentiated carcinoma present

MICROSCOPIC EXAMINATION:

Microscopic examination is performed.

PATHOLOGIC STAGE:

PROCEDURE: Bilateral salpingo-oophorectomy, omentectomy, partial colectomy, splenectomy, multiple biopsies as listed below.

PATHOLOGIC STAGE [REDACTED] pT3C pN1 pMX

NOTE: Information on pathology stage and the operative procedure is transmitted to this [REDACTED] required for accreditation by the [REDACTED] stage is based solely upon the current tissue specimen being evaluated, and does not incorporate information on any specimens submitted separately to our Cytology section, past pathology information, imaging studies, or clinical or operative findings. Pathology stage is only a component to be considered in determining the clinical stage, and should not be confused with nor substituted for it.

[page 3 of 4]
The exact operative procedure is available in the surgeon's operative report.

DIAGNOSIS:

A. "OMENTAL NODULE" (BIOPSY, FOR FROZEN SECTION):

METASTATIC PAPILLARY SEROUS ADENOCARCINOMA.

B. "OMENTUM" (OMENTECTOMY):

METASTATIC PAPILLARY SEROUS ADENOCARCINOMA, LARGEST METASTASIS
APPROXIMATELY 14 CM.

C. "RIGHT TUBE AND OVARY" (SALPINGO-OOPHORECTOMY):

PAPILLARY SEROUS ADENOCARCINOMA OF THE OVARY.
FIGO GRADE: 3 OF 3 (POORLY DIFFERENTIATED).
TUMOR SIZE: 9 CM.
SURFACE INVOLVEMENT: PRESENT.
FALLOPIAN TUBE: POSITIVE FOR CARCINOMA.

D. "LEFT GUTTER" (BIOPSY):

METASTATIC PAPILLARY SEROUS ADENOCARCINOMA.

E. "LEFT TUBE AND OVARY" (SALPINGO-OOPHORECTOMY):

OVARY WITH METASTATIC PAPILLARY SEROUS ADENOCARCINOMA.
FALLOPIAN TUBE: NO CANCER SEEN.

F. "CUL DE SAC NODULE" (BIOPSY):

METASTATIC PAPILLARY SEROUS ADENOCARCINOMA.

G. "RECTOSIGMOID" (PARTIAL COLECTOMY):

TWO SEGMENTS OF COLON WITH MULTIPLE DEPOSITS OF METASTATIC PAPILLARY
SEROUS ADENOCARCINOMA, WITH EXTENSIVE LYMPHATIC/VASCULAR INVASION.
TWO PERICOLONIC LYMPH NODES, POSITIVE FOR CARCINOMA (2/2).
MICROSCOPIC DEPOSITS OF CARCINOMA ARE SEEN IN MUCOSAL MARGINS.

H. "RIGHT PELVIC LYMPH NODE" (BIOPSY):

METASTATIC SEROUS CARCINOMA IN ONE LYMPH NODE (1/1).

I. "BLADDER FLAP MASS". (BIOPSY):

PAPILLARY SEROUS ADENOCARCINOMA.

[page 4 of 4]
TCGA-29-1785

J. "LEFT LYMPH NODE" (BIOPSY):

METASTATIC SEROUS CARCINOMA IN ONE LYMPH NODE (1/1).

K. "DONUT" (EXCISION):

COLONIC MUCOSA, NO PATHOLOGIC DIAGNOSIS.
NO EVIDENCE OF MALIGNANCY.

L. "SPLEEN" (SPLENECTOMY):

SPLEEN WITH CAPSULAR RUPTURE.
NO EVIDENCE OF MALIGNANCY.

I certify that I personally conducted the diagnostic evaluation of the above specimen(s) and have rendered the above diagnosis(es).

Performed by:

[REDACTED]

[REDACTED]

Source: NCI Genomic Data Commons file 9c21be97-662e-480b-bdc5-45c84f9a6d40 (TCGA-29-1785.B520ED75-17DD-420F-B444-4436BB03F40F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).